Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-5890, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-5890-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Specimens Submitted:

with large left renal mass.

Specimens Submitted:

- 1: SP: Left kidney and ureter
- 2: SP: Para aortic lymph nodes
- 3: SP: Preaortic lymph nodes
- 4: SP: Suprahilar lymph nodes and adrenal gland

DIAGNOSIS:

1. SP: Left kidney and ureter:

Tumor Type:

Renal cell carcinoma - Unclassified type

The tumor is high grade with a combination of papillary, tubular and clear cell features and focal desmoplastic stroma.

Tumor Size:

Greatest diameter is 11.5 cm.

Local Invasion (for renal cortical types):

Involves renal sinus fat

Tumor involves perinephric fat

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

chronic pyelonephritis, nephrocalcinosis and focal cortical scarring and cysts.

Adrenal Gland:

Not identified

See part 4

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3a Tumor invades the adrenal gland or perinephric tissues but not beyond Gerota's fascia

Comment: The tumor cells are diffusely immunoreactive for RACEMASE and CD10; and focally positive for CEA, 34BE12, and CK7. CAIX and cytokeratin AE1-AE3 are negative in tumor cells.

[page 2 of 3]
2. Para aortic lymph nodes; dissection:
- Nine benign lymph nodes (0/9).
3. Preaortic lymph nodes:
- Ten benign lymph nodes (0/10).
4. Suprahilar lymph nodes and adrenal gland:
- Benign adrenal tissue.
- No lymphoid tissue identified.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result

Special Stain
CK7
RACEMASE
CA-1X,
CD10
34BE12
CEA P
AE1:AE3
IMM RECUT
NEG CONT

Comment

Gross Description:

1) The specimen is received fresh labeled "left kidney and ureter" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 853 g in total. The kidney measures 17.5 x 11 x 9 cm. The attached ureter measures 11 cm in length and 0.3 cm in diameter. The attached renal vein measures 1.4 cm in length and 0.5 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is not identified. The kidney is inked black and bivalved to reveal a hemorrhagic bright yellow to tan friable mass at the upper pole of the kidney measuring 11.5 x 9 x 8 cm. The mass is sharply circumscribed from the adjacent kidney parenchyma and grossly extends into the perinephric fat and abuts Gerota's fascia which is inked black. Tumor extends to within 0.5 cm of the renal sinus. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined corticomedullary junction and several cortical cysts filled with straw colored serous fluid in the inferior portion of the kidney measuring up to 2 cm in greatest dimension each. The cortex measures 0.7 cm and the calyces appear normal. Lymph nodes are not identified in the perinephric fat. The specimen is photographed. Representative sections are submitted for [redacted] and for permanent sections.

Summary of sections:

UVM -- ureteral and vessel margins
T-- tumor
TPF-- tumor with perinephric fat
IG - tumor with Gerota's fascia
SF - sinus fat closest to tumor
K -- representative sections kidney
C - cortical cysts

2). The specimen is received in formalin, labeled "Para-aortic lymph nodes" and consists of six pink tan firm, fatty lymph nodes ranging from 0.5 to 2.7 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes

[page 3 of 3]
[REDACTED]

BLN-- bisected lymph node

[REDACTED]

3). The specimen is received in formalin, labeled "Preaortic lymph nodes" and consists of seven pink tan firm, fatty lymph nodes ranging from 1 to 3.2 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes

BLN-- bisected lymph node

[REDACTED]

4). The specimen is received in formalin, labeled "Suprahilar lymph nodes and adrenal gland" and consists of a 8 x 3 x 2 cm portion of fibroadipose tissue. Cut sections reveal three yellow tan fatty lymph nodes varying from 0.7 to 1.2 cm. A cystic golden yellow adrenal membrane is identified, measuring 1.5 x 1.5 x 0.5 cm. All identified lymph nodes are submitted. Entirely submitted.

Summary of sections:

A -- adrenal gland

LN -- lymph nodes

Summary of Sections:

Part 1: SP: Left kidney and ureter

Block	Sect. Site	PCs
4	add	4
1	C	1
1	K	1
3	SF	3
2	T	4
2	TG	2
3	TPF	3
1	uvm	1

Part 2: SP: Para aortic lymph nodes

Block	Sect. Site	PCs
2	BLN	2
2	LN	5

Part 3: SP: Preaortic lymph nodes

Block	Sect. Site	PCs
2	BLN	2
4	LN	4

Part 4: SP: Suprahilar lymph nodes and adrenal gland

Block	Sect. Site	PCs
3	A	3
2	LN	2

Source: NCI Genomic Data Commons file 94d15909-3852-4aff-be50-47cecec34da7 (TCGA-BQ-5890.70B1F0D2-9E63-4ABD-90AB-6A9E59245078.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).